FM case AD1717 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/b4e39a97-eb0e-4d1d-8959-a97ec6d323f6

Female, 41.1 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
